Somatic mutation profile of tumor specimen TCGA-2A-A8VO-01A (aliquot TCGA-2A-A8VO-01A-11D-A377-08) from TCGA case TCGA-2A-A8VO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.4 years (20,958 days).
Specimen TCGA-2A-A8VO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 958ece8f-f334-4356-afb0-a0a46d2e8229.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-A8VO-10A (Blood Derived Normal), aliquot TCGA-2A-A8VO-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea19ce5c-666c-444e-9ea1-c050f9d76a8b

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATAD2B | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 48/205 reads (23%) | catalogued as rs1553188314, COSV100897895; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.10520G>A p.G3507D | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55084086, COSV55084099; called by muse, mutect2, varscan2
- ANKK1 | c.2047G>T p.A683S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100392904, COSV58273176; called by muse, mutect2, varscan2
- B4GALT2 | c.50T>A p.L17H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs756643777, COSV99356497; called by muse, varscan2
- BRINP3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs866742953, COSV66521468; called by muse, mutect2, varscan2
- CCDC87 | c.1089G>C p.K363N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100040026; called by muse, mutect2, varscan2
- DCHS1 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.623); catalogued as rs746752715, COSV100202155; called by muse, mutect2, varscan2
- DNAH11 | c.10091G>A p.R3364Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs369682703; called by muse, mutect2, varscan2
- ERBB3 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99917065; called by muse, mutect2, varscan2
- ERBB3 | c.894A>T p.Q298H | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99917067; called by muse, mutect2, varscan2
- GRIN2B | c.3038C>T p.T1013I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs202109019, COSV101663066; called by muse, mutect2, varscan2
- HDGF | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100625765; called by muse, mutect2
- IGSF1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100812127; called by muse, mutect2, varscan2
- KRT9 | c.1052A>G p.Q351R | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV99879240; called by muse, mutect2, varscan2
- MED12L | c.2599A>C p.K867Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99853468; called by muse, mutect2, varscan2
- PIWIL1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV55346511, COSV99806728; called by muse, mutect2, varscan2
- PSG7 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101343265, COSV68445724; called by muse, mutect2, varscan2
- RBM19 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138978572; called by muse, mutect2, varscan2
- STXBP5L | c.2094C>A p.N698K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1425476413, COSV99874640; called by muse, mutect2, varscan2
- TBXAS1 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV54953327, COSV99695459; called by muse, mutect2, varscan2
- TIAM1 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs531274411, COSV54570050; called by muse, mutect2, varscan2
- ZNF182 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV100527080; called by muse, mutect2, varscan2
- AQP5 | c.441_450del p.F147Lfs*35 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- LCORL | c.494_495del p.I165Tfs*6 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- CEP135 | c.3294G>A p.R1098= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV99954515; called by muse, mutect2, varscan2
- GTPBP4 | c.615G>A p.L205= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100672713; called by muse, mutect2, varscan2
- P4HTM | c.939G>A p.P313= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs774249985, COSV100637556; called by muse, mutect2, varscan2
- TIE1 | c.2358C>T p.I786= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100992094; called by muse, mutect2, varscan2
- TP63 | c.1095G>A p.S365= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs748609799, COSV53219679; called by muse, mutect2, varscan2
- ZNF285 | c.762C>T p.H254= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs1453395546, COSV100450025; called by muse, mutect2
